Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81R, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81R-01A (Primary Tumor).

Unique Patient Identifier:

Short descriptive translation of the pathology report as provided by the

Date report:

Material received:

Material: left adrenal

Macroscopic findings:

within the normal appearing adrenal well discernible tumor of 3.5x3.2x3 cm size with brown appearance and concentric reddish areas.

Microscopic findings:

Confluent neoplasia of the adrenal medulla with partial compression of the adrenal cortex. Tumor cells with oval shaped eccentric nuclei of middle size with peripheral nucleoli and large amounts of chromatin. Mitotic rate at 2 per 10 HPF. No vascular invasion, no necrosis. Expression for inhibin alpha and S-100.

Conclusion:

Pheochromocytoma of the left adrenal

Translated by:

ICD-O-3
Pheochromocytoma NOS 8700/0
Site Adrenal gland NOS C74.9
QW 10/17/13

Source: NCI Genomic Data Commons file 58e0dc6d-c605-4484-977e-486241fe712c (TCGA-WB-A81R.590DB337-349F-44F5-9335-1CB3148CB63E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).